Somatic mutation profile of tumor specimen MP2PRT-PAPGEE-TMP1-A (aliquot MP2PRT-PAPGEE-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPGEE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,291 days).
Specimen MP2PRT-PAPGEE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e22a728-0497-4d4a-9dcc-1e010ab60984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGEE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGEE-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21cbfb6-83c2-4f45-ab3b-8f2993db67d9

The open-access MAF lists 23 somatic variants for this specimen: 10 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 10, Missense Mutation 7, In Frame Ins 3, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUZD1 | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 212/517 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201005450; called by muse, mutect2, varscan2
- DUSP12 | c.57delinsGGGG p.S19delinsRG | In Frame Ins (INS) | VAF 144/375 reads (38%) | catalogued as COSV63411158; called by mutect2*, pindel, varscan2*
- FAM184A | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 168/390 reads (43%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.993); catalogued as rs779916036, COSV100138500; called by muse, mutect2, varscan2
- MXRA8 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 144/582 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58511074; called by muse, mutect2, varscan2
- PCDHB6 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 150/711 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as rs1274457917, COSV99169997; called by muse, mutect2, varscan2
- DUSP12 | c.56_57insGGG p.S19delinsRG | In Frame Ins (INS) | VAF 114/314 reads (36%) | called by mutect2, varscan2
- ERG | c.400_401insGCCCTTTGGACGCCG p.I133_V134insGPLDA | In Frame Ins (INS) | VAF 68/257 reads (26%) | called by mutect2, pindel, varscan2
- FAM83B | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 141/319 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- IKZF1 | c.1394_1399delinsGGAGGG p.E465_C467delinsGRG | Missense Mutation (ONP) | VAF 166/524 reads (32%) | called by pindel, varscan2*
- MXRA8 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA10 | c.3264T>C p.Y1088= | Silent (SNP) | VAF 89/209 reads (43%) | called by muse, mutect2, varscan2
- ADAM12 | c.1020T>C p.N340= | Silent (SNP) | VAF 130/293 reads (44%) | called by muse, mutect2, varscan2
- ASB15 | c.528G>A p.K176= | Silent (SNP) | VAF 140/362 reads (39%) | catalogued as rs746570652; called by muse, mutect2, varscan2
- CHST11 | c.711C>T p.F237= | Silent (SNP) | VAF 159/390 reads (41%) | catalogued as COSV57985343; called by muse, mutect2, varscan2
- FAT1 | c.13230A>T p.T4410= | Silent (SNP) | VAF 163/431 reads (38%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.336A>G p.V112= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs782239949; called by muse, varscan2
- MXRA8 | c.858C>G p.V286= | Silent (SNP) | VAF 129/536 reads (24%) | called by muse, mutect2, varscan2
- NMNAT2 | c.36C>T p.L12= | Silent (SNP) | VAF 135/356 reads (38%) | called by muse, mutect2, varscan2
- NXPE1 | c.1530C>T p.N510= (on ENST00000424269; = p.N368= on NM_152315.5) | Silent (SNP) | VAF 173/427 reads (41%) | catalogued as rs765591762; called by muse, mutect2, varscan2
- PRDM13 | c.972C>T p.L324= | Silent (SNP) | VAF 241/576 reads (42%) | called by muse, mutect2, varscan2
- COPRS | c.99+335G>A | Intron (SNP) | VAF 158/408 reads (39%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+26221A>T | Intron (SNP) | VAF 102/233 reads (44%) | called by muse, mutect2, varscan2
- PDGFRA | c.628+15T>C | Intron (SNP) | VAF 156/350 reads (45%) | called by muse, mutect2, varscan2
